Somatic mutation profile of tumor specimen MMRF_1137_2_BM_CD138pos (aliquot MMRF_1137_2_BM_CD138pos_T6_KHS5U_L08856) from MMRF case MMRF_1137, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.8 years (24,046 days).
Specimen MMRF_1137_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eab320f2-47da-4102-b676-1c8263acf1b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1137_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1137_1_PB_Whole_C1_KHS5U_L13429; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d58ae47b-6910-4399-9693-b00eac9e9dd5

The open-access MAF lists 155 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 78 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 40, Intron 19, Silent 17, RNA 10, 5'UTR 7, Splice Region 3, Splice Site 3, Frame Shift Del 2, Nonsense Mutation 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 37/141 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- ERBB3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 17/140 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV57246601, COSV57252959; called by muse, mutect2, varscan2
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 29/99 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 134/373 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 22/330 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2
- ACE | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770628079, COSV52010307; called by muse, mutect2, varscan2
- ANKRD53 | c.896A>C p.E299A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV55537989; called by muse, mutect2
- ARHGAP11A | c.2021T>C p.F674S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs752293185; called by muse, mutect2, varscan2
- ASTN1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs148425095; called by muse, mutect2, varscan2
- B3GAT1 | c.80G>C p.S27T | Missense Mutation (SNP) | VAF 79/125 reads (63%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.039); catalogued as COSV56998981; called by muse, mutect2, varscan2
- CARD6 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 35/299 reads (12%) | catalogued as rs62357606; called by muse, mutect2, varscan2
- CCDC30 | c.1046C>T p.S349L (on ENST00000340612; = p.S306L on NM_001080850.3) | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773805083; called by muse, mutect2
- CLNK | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57020198; called by muse, mutect2, varscan2
- FAM170A | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1166722525; called by muse, mutect2
- FAM184B | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1160276217, COSV99401210; called by muse, mutect2, varscan2
- FLYWCH1 | c.1240G>A p.A414T (on ENST00000253928 / NM_001308068.2; = p.A413T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs529892902, COSV54146544; called by muse, mutect2, varscan2
- GLRB | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.197); catalogued as rs1355064370; called by muse, mutect2, varscan2
- GRID2IP | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745505031; called by muse, mutect2, varscan2
- IFIT5 | c.1276A>G p.K426E | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs1166831709; called by muse, mutect2, varscan2
- IGLV3-1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as rs529856363; called by muse, mutect2
- IGLV5-45 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs773829774; called by muse, mutect2, varscan2
- KRTAP4-8 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs753185136; called by muse, mutect2, varscan2
- LRFN1 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99953242; called by muse, mutect2, varscan2
- LRP3 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.489); catalogued as rs752590244; called by muse, mutect2, varscan2
- NCKIPSD | c.172-3dup | Splice Region (INS) | VAF 12/32 reads (38%) | catalogued as rs768132931; called by mutect2, varscan2
- NF1 | c.6643-2del p.X2215_splice (on ENST00000358273 / NM_001042492.3; = p.X2194_splice on NM_000267.3) | Splice Site (DEL) | VAF 8/82 reads (10%) | catalogued as CS1311543, COSV100646014; called by mutect2, pindel
- OR7C2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV50181190; called by muse, mutect2, varscan2
- PIK3CG | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63246545; called by muse, mutect2
- PRELID3B | c.90C>G p.N30K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV63504991; called by muse, mutect2, varscan2
- PRR23B | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV61493538; called by muse, mutect2, varscan2
- PRRC1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs753950329; called by muse, mutect2, varscan2
- SLC22A2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1017655480; called by muse, mutect2, varscan2
- SNX29P1 | n.185C>T | Splice Region (SNP) | VAF 19/42 reads (45%) | catalogued as rs1438733146; called by mutect2, varscan2
- TAPBP | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747417254; called by muse, mutect2, varscan2
- ZMYM3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58737172; called by muse, mutect2
- ABCA12 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); called by muse, mutect2
- ADAMTS2 | c.1864T>C p.F622L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ARNT2 | c.2134T>C p.F712L | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- CCIN | c.1708C>A p.L570M | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CORO7 | c.1519A>C p.N507H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBLN1 | c.1574-2A>C p.X525_splice | Splice Site (SNP) | VAF 29/202 reads (14%) | called by muse, mutect2, varscan2
- HAO2 | c.59_72del p.S20Yfs*2 | Frame Shift Del (DEL) | VAF 102/360 reads (28%) | called by mutect2, pindel, varscan2
- KIAA2026 | c.84C>A p.D28E | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF26A | c.3876G>T p.R1292S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MYOCD | c.1871T>A p.L624H | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.706); called by muse, mutect2
- PEDS1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHYHIPL | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2
- RXFP1 | c.216T>A p.F72L | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RXFP2 | c.1638G>C p.W546C | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA6 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTBN4 | c.680T>G p.V227G | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2
- STRA8 | c.447-3C>T | Splice Region (SNP) | VAF 17/201 reads (8%) | called by muse, mutect2
- SYN2 | c.1582C>G p.P528A | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TASOR | c.2335C>G p.L779V (on ENST00000355628 / NM_001365636.2; = p.L383V on NM_015224.3) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TGS1 | c.1764_1765del p.D590Qfs*9 | Frame Shift Del (DEL) | VAF 34/168 reads (20%) | called by mutect2, pindel, varscan2
- TRHDE | c.1019C>A p.T340K | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZNF225 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ZNF277 | c.294-1G>A p.X98_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- ZSCAN5C | c.1417T>G p.C473G | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- BTBD1 | c.396G>T p.L132= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- CAMK2B | c.648C>T p.D216= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as rs773815200, COSV99323379; called by muse, mutect2, varscan2
- DNAH5 | c.10944T>C p.L3648= | Silent (SNP) | VAF 47/146 reads (32%) | called by muse, mutect2, varscan2
- ENPP6 | c.465A>T p.L155= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- GALR1 | c.672T>A p.L224= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- GLB1L2 | c.813G>A p.Q271= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- IGHV5-51 | c.66G>A p.Q22= | Silent (SNP) | VAF 90/244 reads (37%) | catalogued as rs567423875; called by muse, varscan2
- IGLL5 | c.114G>A p.L38= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs556230331, COSV73249618, COSV73250730; called by muse, varscan2
- IGLV3-1 | c.336C>T p.S112= | Silent (SNP) | VAF 43/73 reads (59%) | catalogued as rs73880716; called by muse, mutect2, varscan2
- IGLV7-46 | c.228C>T p.H76= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as rs185250547; called by muse, mutect2, varscan2
- KCTD15 | c.687G>A p.S229= | Silent (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- LTBP2 | c.1281C>T p.C427= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs375630948; called by muse, mutect2, varscan2
- MRPL38 | c.456T>G p.A152= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- PCDHAC1 | c.2220C>A p.A740= | Silent (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- SLC27A2 | c.1839A>C p.I613= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- TMEM132D | c.528C>A p.T176= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV101397450, COSV70611344; called by muse, varscan2
- TP53BP1 | c.2301A>G p.R767= | Silent (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- AC100868.1 | c.*76C>T | 3'UTR (SNP) | VAF 47/120 reads (39%) | called by muse, mutect2, varscan2
- AC124067.4 | n.1635C>T | RNA (SNP) | VAF 18/76 reads (24%) | called by muse, varscan2
- AC136759.1 | n.972G>T | RNA (SNP) | VAF 73/156 reads (47%) | catalogued as rs747479276; called by muse, mutect2, varscan2
- ACOT11 | c.-10A>T | 5'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- AGBL4 | c.*558A>G | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- AGMO | c.*210C>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- AL356414.1 | n.47G>T | RNA (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- AP3B2 | c.1971+160G>C | Intron (SNP) | VAF 30/102 reads (29%) | catalogued as rs1009956106; called by muse, mutect2, varscan2
- ARHGAP32 | c.*3764A>T | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- BCL7A | chr12:122021085 A>G | 5'Flank (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.847C>A | RNA (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- C8orf82 | c.157-297G>A | Intron (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- CAPN3 | c.1782+259C>A | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- CCDC148 | c.*199A>T | 3'UTR (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- COL4A1 | c.*555G>T | 3'UTR (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- DDX19A | c.*230del | 3'UTR (DEL) | VAF 26/86 reads (30%) | catalogued as rs1187249545; called by mutect2, pindel, varscan2
- DSEL | c.*1829G>C | 3'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- DTX1 | c.-452G>A | 5'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as COSV57495139; called by muse, varscan2
- EGR3 | c.*1608C>T | 3'UTR (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- EMP1 | c.*377C>A | 3'UTR (SNP) | VAF 6/133 reads (5%) | called by muse, mutect2
- EPS8L1 | c.*146A>G | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
- FAM102A | c.-72G>C | 5'UTR (SNP) | VAF 68/145 reads (47%) | called by muse, mutect2, varscan2
- FAM220BP | n.365G>A | RNA (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- FBN1 | c.*530G>T | 3'UTR (SNP) | VAF 12/83 reads (14%) | catalogued as rs959092536; called by muse, mutect2, varscan2
- FES | c.*52C>T | 3'UTR (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- GLIS3 | c.*2025A>T | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.*665T>C | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2
- HES2 | c.*737G>T | 3'UTR (SNP) | VAF 47/137 reads (34%) | called by muse, mutect2, varscan2
- HIF1AN | c.*1321A>T | 3'UTR (SNP) | VAF 9/159 reads (6%) | called by muse, mutect2
- HSPA1B | chr6:31834909 T>G | 3'Flank (SNP) | VAF 15/34 reads (44%) | catalogued as rs950520942; called by muse, mutect2, varscan2
- IGLV1-41 | n.117G>A | RNA (SNP) | VAF 24/66 reads (36%) | called by muse, varscan2
- IGLV1-41 | n.210G>A | RNA (SNP) | VAF 42/106 reads (40%) | catalogued as rs527833904; called by muse, varscan2
- IGLV1-41 | n.267A>G | RNA (SNP) | VAF 36/102 reads (35%) | called by muse, varscan2
- IL36RN | c.*1601G>A | 3'UTR (SNP) | VAF 12/52 reads (23%) | catalogued as rs373510838; called by muse, mutect2, varscan2
- IL4R | c.671-93G>A | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs1330020488; called by muse, mutect2
- ITPR2 | c.708+144G>A | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- KPNA5 | c.*45+2631C>G | Intron (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- LIN28B | c.*4038G>A | 3'UTR (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- MAP2K3 | c.50-2699C>G | Intron (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- MCM3AP | c.5039-56A>G | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- MEGF9 | c.*3201A>T | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, varscan2
- MRPL52 | c.28+40T>C | Intron (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- MSR1 | c.1033+2913G>T | Intron (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- MYO1C | c.-180C>G | 5'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as rs1353813909; called by muse, mutect2
- NCK2 | c.*510G>T | 3'UTR (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- NDUFAF4 | c.*519C>A | 3'UTR (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- NDUFAF4 | c.*206C>A | 3'UTR (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- NLGN1 | c.*3453A>G | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- NOX4 | c.58-101A>T | Intron (SNP) | VAF 114/295 reads (39%) | catalogued as COSV54451737; called by muse, mutect2, varscan2
- OR51E2 | c.*1160G>A | 3'UTR (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- PCSK5 | c.2626+5737G>A | Intron (SNP) | VAF 18/42 reads (43%) | catalogued as rs1185878130; called by muse, mutect2, varscan2
- PIK3CD | c.*400G>T | 3'UTR (SNP) | VAF 11/221 reads (5%) | called by muse, mutect2
- POR | c.-18C>T | 5'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- PPP2R2B | c.-260G>T | 5'UTR (SNP) | VAF 9/114 reads (8%) | catalogued as rs1010654317; called by muse, mutect2
- PSPH | c.*36G>A | 3'UTR (SNP) | VAF 27/70 reads (39%) | catalogued as rs762540857; called by muse, mutect2, varscan2
- RAB34 | c.*263C>A | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- RIC3 | c.522-1412G>A | Intron (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.*1025C>A | 3'UTR (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- RSPO3 | c.*635G>T | 3'UTR (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- RSPO3 | c.*956G>C | 3'UTR (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- RSPRY1 | c.*940C>T | 3'UTR (SNP) | VAF 10/32 reads (31%) | catalogued as rs1372666769; called by muse, mutect2, varscan2
- SCN3B | c.*2522C>G | 3'UTR (SNP) | VAF 29/45 reads (64%) | called by muse, mutect2, varscan2
- SCP2 | c.1548+1271T>C | Intron (SNP) | VAF 6/131 reads (5%) | called by muse, mutect2
- SLC23A2 | c.1102+37C>T | Intron (SNP) | VAF 10/39 reads (26%) | catalogued as rs754759159, COSV57776918; called by muse, mutect2, varscan2
- SLC9A3 | c.*1996C>T | 3'UTR (SNP) | VAF 38/133 reads (29%) | catalogued as rs929206424; called by muse, mutect2, varscan2
- SPDL1 | c.160-282A>G | Intron (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- SPSB4 | c.*778A>T | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- STAM2 | c.*2112C>T | 3'UTR (SNP) | VAF 3/44 reads (7%) | catalogued as rs1378822780; called by muse, mutect2
- SYNRG | c.*3622_*3623del | 3'UTR (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
- TACC1 | c.*3150A>C | 3'UTR (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- TAF10 | c.232+34G>A | Intron (SNP) | VAF 28/126 reads (22%) | catalogued as rs1432635281; called by muse, mutect2, varscan2
- TBC1D3P2 | n.189G>A | RNA (SNP) | VAF 9/57 reads (16%) | catalogued as rs1568066702; called by muse, mutect2, varscan2
- TMEM273 | c.294-76T>A | Intron (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- TXNRD3 | n.524A>T | RNA (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- VEGFC | c.-130G>C | 5'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- ZBTB14 | c.*151G>A | 3'UTR (SNP) | VAF 19/106 reads (18%) | called by muse, mutect2, varscan2
- ZC3H3 | c.*394G>A | 3'UTR (SNP) | VAF 26/75 reads (35%) | catalogued as rs530505802; called by muse, mutect2, varscan2
- ZNF462 | c.6832+84C>A | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
